Somatic mutation profile of tumor specimen 0DQMPQ from CCDI case PBCEZL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,780 days).
Specimen 0DQMPQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b019e971-1636-4a8e-b912-4c76a24a8aa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQMQV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5596f695-c498-432a-a60b-d767ed68556e

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 3, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.5464dup p.S1822Ffs*29 | Frame Shift Ins (INS) | VAF 244/578 reads (42%) | catalogued as rs780890209; called by mutect2, varscan2
- CNGB3 | c.567G>T p.W189C | Missense Mutation (SNP) | VAF 45/609 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60685105; called by muse, mutect2
- KDM6A | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 428/452 reads (95%) | catalogued as rs189751539, CM146948, COSV65037198; called by muse, mutect2, varscan2
- TBC1D24 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as rs770787878; called by muse, mutect2, varscan2
- TBR1 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 362/786 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67417745; called by mutect2, varscan2
- USH2A | c.7882C>A p.P2628T | Missense Mutation (SNP) | VAF 38/712 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV100232583, COSV56460347; called by muse, mutect2
- COL28A1 | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 222/500 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- LRRC28 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 341/723 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ADAMTS7 | c.4338C>T p.C1446= | Silent (SNP) | VAF 204/369 reads (55%) | catalogued as rs760216802; called by muse, mutect2, varscan2
- LRRC8B | c.1359G>A p.V453= | Silent (SNP) | VAF 336/746 reads (45%) | called by muse, mutect2, varscan2
- RPGRIP1 | c.3426G>T p.V1142= | Silent (SNP) | VAF 319/671 reads (48%) | called by muse, mutect2, varscan2
- SLC1A1 | c.816A>G p.E272= | Silent (SNP) | VAF 330/726 reads (45%) | catalogued as rs759696363; called by muse, mutect2, varscan2
- CLEC12A | c.191-45C>T | Intron (SNP) | VAF 127/416 reads (31%) | called by muse, mutect2, varscan2
- GRAMD2B | c.735+85G>C | Intron (SNP) | VAF 65/338 reads (19%) | called by muse, mutect2, varscan2
- HCN3 | c.870+47C>A | Intron (SNP) | VAF 41/554 reads (7%) | called by muse, mutect2
- RFK | c.*100A>C | 3'UTR (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2
